Somatic mutation profile of tumor specimen TCGA-BR-7901-01A (aliquot TCGA-BR-7901-01A-11D-2201-08) from TCGA case TCGA-BR-7901, project TCGA-STAD (Stomach Adenocarcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Cardia, NOS; AJCC pathologic stage: Stage IIB; Tumor grade: G2; Age at diagnosis: 74.0 years (27,031 days).
Specimen TCGA-BR-7901-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 87201cae-c33c-4908-b22c-365cc56b6aec.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-BR-7901-10A (Blood Derived Normal), aliquot TCGA-BR-7901-10A-01D-2201-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ce0749f4-1b09-4558-86b9-0f91e2614736

The open-access MAF lists 166 somatic variants for this specimen: 116 protein-altering or splice-affecting, 47 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 107, Silent 47, Nonsense Mutation 3, In Frame Ins 2, Splice Site 2, 3'UTR 2, Frame Shift Del 1, Intron 1, Translation Start Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- C6 | c.2450A>C p.K817T | Missense Mutation (SNP) | VAF 23/279 reads (8%) | hotspot (GDC flag); SIFT tolerated (0.4); PolyPhen benign (0.031); catalogued as COSV54704910, COSV54705322; called by muse, mutect2
- ERBB4 | c.3305T>G p.F1102C | Missense Mutation (SNP) | VAF 6/88 reads (7%) | hotspot (GDC flag); SIFT tolerated (0.11); PolyPhen benign (0); catalogued as COSV100728834, COSV61461348; called by muse, mutect2
- ACSM2A | c.1672A>C p.I558L (on ENST00000219054; = p.I479L on NM_001308169.2) | Missense Mutation (SNP) | VAF 12/239 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV54587693; called by muse, mutect2
- ACTN2 | c.1709G>C p.G570A | Missense Mutation (SNP) | VAF 8/81 reads (10%) | SIFT tolerated (0.35); PolyPhen benign (0.001); catalogued as COSV63977093; called by muse, mutect2, varscan2
- ACTR8 | c.896C>G p.S299C | Missense Mutation (SNP) | VAF 12/120 reads (10%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.879); catalogued as COSV51637822; called by muse, mutect2, varscan2
- ADORA3 | c.346G>A p.V116I | Missense Mutation (SNP) | VAF 7/45 reads (16%) | SIFT tolerated (0.55); PolyPhen benign (0.003); catalogued as rs766923748, COSV53986544; called by muse, mutect2, varscan2
- AFF3 | c.182A>T p.K61M | Missense Mutation (SNP) | VAF 11/148 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57864438; called by muse, mutect2
- AJAP1 | c.1043C>A p.T348K | Missense Mutation (SNP) | VAF 4/47 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV65452314; called by muse, mutect2
- ANGPT1 | c.648A>C p.K216N | Missense Mutation (SNP) | VAF 8/52 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.883); catalogued as COSV52449418; called by muse, mutect2, varscan2
- ARHGEF12 | c.3573A>C p.K1191N | Missense Mutation (SNP) | VAF 17/84 reads (20%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.003); catalogued as COSV63106328; called by muse, mutect2, varscan2
- ATP6AP1 | c.1364G>A p.R455H | Missense Mutation (SNP) | VAF 21/185 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1243834914, COSV63896065; called by muse, mutect2, varscan2
- ATP6V1D | c.2T>A p.M1? | Translation Start Site (SNP) | VAF 7/64 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53600206; called by muse, mutect2, varscan2
- BCHE | c.894A>C p.Q298H | Missense Mutation (SNP) | VAF 13/98 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.035); catalogued as COSV52259949; called by muse, mutect2, varscan2
- C2orf42 | c.1582C>G p.P528A | Missense Mutation (SNP) | VAF 5/107 reads (5%) | SIFT deleterious (0.01); PolyPhen benign (0.142); catalogued as COSV52451787; called by muse, mutect2
- CALHM1 | c.952G>A p.E318K | Missense Mutation (SNP) | VAF 4/38 reads (11%) | SIFT tolerated (0.53); PolyPhen benign (0.001); catalogued as COSV53297363, COSV99588726; called by muse, varscan2
- CCDC88C | c.2149C>T p.R717C | Missense Mutation (SNP) | VAF 10/54 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); catalogued as rs757785765, COSV101105862, COSV66240015; called by mutect2, varscan2
- CDK15 | c.185C>T p.A62V (on ENST00000652192 / NM_001366386.2; = p.A11V on NM_139158.2) | Missense Mutation (SNP) | VAF 26/163 reads (16%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.036); catalogued as COSV53636629; called by muse, mutect2, varscan2
- CEP85L | c.953A>C p.Y318S | Missense Mutation (SNP) | VAF 6/108 reads (6%) | SIFT tolerated (0.41); PolyPhen benign (0.3); catalogued as COSV62646335; called by muse, mutect2
- CFAP94 | c.1952A>G p.Q651R (on ENST00000320267 / NM_001352064.2; = p.Q657R on NM_018272.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 12/84 reads (14%) | SIFT tolerated (0.07); PolyPhen benign (0.044); catalogued as COSV57234960; called by muse, mutect2, varscan2
- CFHR3 | c.119G>A p.R40K | Missense Mutation (SNP) | VAF 12/87 reads (14%) | SIFT tolerated (0.36); PolyPhen probably damaging (0.951); catalogued as COSV66402118, COSV66402854; called by mutect2, varscan2
- CHPT1 | c.859A>G p.T287A | Missense Mutation (SNP) | VAF 15/55 reads (27%) | SIFT tolerated (0.27); PolyPhen benign (0.009); catalogued as COSV57534327; called by muse, mutect2, varscan2
- CNBD1 | c.1187T>C p.L396P | Missense Mutation (SNP) | VAF 4/44 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV73072298, COSV73072404, COSV73073941; called by muse, mutect2, varscan2
- CNTN4 | c.460A>G p.S154G | Missense Mutation (SNP) | VAF 26/148 reads (18%) | SIFT tolerated (0.23); PolyPhen benign (0.073); catalogued as COSV61867840, COSV61877283; called by muse, mutect2, varscan2
- CNTN6 | c.314T>G p.L105R | Missense Mutation (SNP) | VAF 33/214 reads (15%) | SIFT deleterious (0.03); PolyPhen benign (0.104); catalogued as COSV63164865, COSV63182098; called by muse, mutect2, varscan2
- COL1A2 | c.1067A>T p.E356V | Missense Mutation (SNP) | VAF 9/69 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.543); catalogued as COSV51962545; called by muse, mutect2, varscan2
- DACH1 | c.679C>T p.H227Y | Missense Mutation (SNP) | VAF 9/104 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV57512050; called by muse, mutect2
- DCLRE1A | c.2281A>T p.N761Y | Missense Mutation (SNP) | VAF 34/121 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.005); catalogued as COSV63749282; called by muse, mutect2, varscan2
- DDX31 | c.1858G>A p.A620T | Missense Mutation (SNP) | VAF 10/116 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs755069984, COSV64650270, COSV64650741; called by muse, mutect2
- DNAH9 | c.7613A>G p.K2538R | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT tolerated (0.16); PolyPhen benign (0.319); catalogued as COSV52364730; called by muse, mutect2, varscan2
- DNTT | c.931G>A p.V311I | Missense Mutation (SNP) | VAF 22/247 reads (9%) | SIFT tolerated (0.58); PolyPhen benign (0.022); catalogued as rs749994764, COSV64523086; called by muse, mutect2
- DPF3 | c.853G>A p.A285T | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.053); catalogued as rs368158261; called by muse, mutect2, varscan2
- DPP10 | c.1664T>G p.F555C | Missense Mutation (SNP) | VAF 18/128 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV59706886; called by muse, mutect2, varscan2
- DPYD | c.1844A>C p.E615A | Missense Mutation (SNP) | VAF 10/93 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64608274; called by muse, mutect2
- DYNC2H1 | c.10811C>T p.A3604V | Missense Mutation (SNP) | VAF 5/50 reads (10%) | SIFT tolerated (0.24); PolyPhen benign (0); catalogued as COSV62101129; called by muse, mutect2, varscan2
- ERN1 | c.2548G>T p.E850* | Nonsense Mutation (SNP) | VAF 6/96 reads (6%) | catalogued as COSV101458480; called by muse, mutect2
- EVI2A | c.16G>A p.E6K | Missense Mutation (SNP) | VAF 24/346 reads (7%) | SIFT tolerated (0.14); PolyPhen benign (0.007); catalogued as rs759341310, COSV55986615; called by muse, mutect2
- EYA4 | c.223G>T p.V75F | Missense Mutation (SNP) | VAF 4/70 reads (6%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.226); catalogued as COSV62057665; called by muse, mutect2
- FEM1A | c.1346G>A p.R449Q | Missense Mutation (SNP) | VAF 15/178 reads (8%) | SIFT tolerated (0.19); PolyPhen benign (0.197); catalogued as rs1327932096, COSV54164478; called by muse, mutect2, varscan2
- FLG | c.590G>T p.R197M | Missense Mutation (SNP) | VAF 7/144 reads (5%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.787); catalogued as COSV100911834; called by muse, mutect2
- FLG2 | c.172A>G p.M58V | Missense Mutation (SNP) | VAF 7/115 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV66171125; called by muse, mutect2
- GLI3 | c.4313A>C p.N1438T | Missense Mutation (SNP) | VAF 10/134 reads (7%) | SIFT tolerated (0.08); PolyPhen benign (0.054); catalogued as COSV67892426; called by muse, mutect2
- GPER1 | c.787G>A p.A263T | Missense Mutation (SNP) | VAF 9/64 reads (14%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.866); catalogued as rs958800961, COSV52467860; called by muse, mutect2, varscan2
- HOXD10 | c.907G>A p.V303I | Missense Mutation (SNP) | VAF 35/144 reads (24%) | SIFT tolerated (0.34); PolyPhen possibly damaging (0.683); catalogued as rs373028650; called by muse, mutect2, varscan2
- HRNR | c.8398C>G p.Q2800E | Missense Mutation (SNP) | VAF 26/257 reads (10%) | SIFT deleterious (0.03); PolyPhen benign (0.031); catalogued as COSV64260805; called by muse, varscan2
- IFT88 | c.1381G>C p.A461P (on ENST00000319980 / NM_001318493.2; = p.A452P on NM_006531.5 and 9 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 9/135 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.852); catalogued as COSV100179798, COSV60673064; called by muse, mutect2
- IGLV11-55 | c.58C>T p.R20W | Missense Mutation (SNP) | VAF 20/49 reads (41%) | SIFT deleterious (0.01); PolyPhen benign (0.288); catalogued as rs563366562, COSV101135353, COSV101135380; called by muse, mutect2
- IMPG1 | c.1235T>G p.L412R | Missense Mutation (SNP) | VAF 13/74 reads (18%) | SIFT deleterious (0.04); PolyPhen benign (0.031); catalogued as COSV64060055; called by muse, mutect2, varscan2
- IMPG2 | c.3044A>T p.K1015M | Missense Mutation (SNP) | VAF 13/106 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV51981407, COSV51981974, COSV51983300; called by muse, mutect2, varscan2
- INTS7 | c.1084C>T p.H362Y | Missense Mutation (SNP) | VAF 19/126 reads (15%) | SIFT tolerated (0.73); PolyPhen possibly damaging (0.542); catalogued as COSV65344907; called by muse, mutect2, varscan2
- IQSEC1 | c.838G>C p.E280Q | Missense Mutation (SNP) | VAF 9/129 reads (7%) | SIFT tolerated (0.39); PolyPhen benign (0.023); catalogued as COSV56226762; called by muse, mutect2
- ITGAM | c.1879T>G p.F627V (on ENST00000648685 / NM_001145808.2; = p.F626V on NM_000632.4) | Missense Mutation (SNP) | VAF 28/416 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54940087, COSV54942272; called by muse, mutect2
- L3MBTL4 | c.1200-1G>T p.X400_splice | Splice Site (SNP) | VAF 5/93 reads (5%) | catalogued as COSV53132992; called by muse, mutect2
- LCE2B | c.239T>C p.L80P | Missense Mutation (SNP) | VAF 10/187 reads (5%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.278); catalogued as COSV64227876; called by muse, mutect2
- LCT | c.1537G>A p.E513K | Missense Mutation (SNP) | VAF 5/82 reads (6%) | SIFT tolerated (0.13); PolyPhen benign (0.322); catalogued as COSV51554322; called by muse, mutect2
- LMX1A | c.938G>A p.R313Q | Missense Mutation (SNP) | VAF 19/114 reads (17%) | SIFT tolerated (0.83); PolyPhen benign (0.005); catalogued as rs768850154, COSV54225152; called by muse, mutect2, varscan2
- MAGEC1 | c.3110T>A p.F1037Y | Missense Mutation (SNP) | VAF 9/60 reads (15%) | SIFT tolerated (0.22); PolyPhen benign (0.021); catalogued as COSV53577793; called by muse, mutect2, varscan2
- MAGEC2 | c.316T>C p.S106P | Missense Mutation (SNP) | VAF 3/34 reads (9%) | SIFT tolerated (0.41); PolyPhen probably damaging (0.961); catalogued as COSV56000667, COSV99909772; called by muse, mutect2
- MAP1A | c.3949C>G p.L1317V | Missense Mutation (SNP) | VAF 9/54 reads (17%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.143); catalogued as rs759276154, COSV55811209; called by muse, mutect2, varscan2
- MMD | c.353T>G p.L118R | Missense Mutation (SNP) | VAF 29/102 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV50435720; called by muse, mutect2, varscan2
- MYO9A | c.1196T>G p.F399C | Missense Mutation (SNP) | VAF 23/99 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV61854804; called by muse, mutect2, varscan2
- MYT1L | c.628A>G p.K210E | Missense Mutation (SNP) | VAF 6/46 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV67715221, COSV67727147; called by muse, varscan2
- NAV3 | c.7105A>G p.S2369G (on ENST00000397909 / NM_001024383.2; = p.S2347G on NM_014903.6) | Missense Mutation (SNP) | VAF 3/43 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.188); catalogued as COSV57099611; called by muse, mutect2
- NELL1 | c.1022T>G p.V341G | Missense Mutation (SNP) | VAF 8/79 reads (10%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.787); catalogued as COSV54299005; called by muse, mutect2
- NLRP8 | c.1282G>A p.V428I | Missense Mutation (SNP) | VAF 56/123 reads (46%) | SIFT tolerated (0.28); PolyPhen benign (0.177); catalogued as rs759351908, COSV52585627; called by muse, mutect2, varscan2
- NUAK1 | c.832+2T>G p.X278_splice | Splice Site (SNP) | VAF 11/131 reads (8%) | catalogued as COSV54606124, COSV99777071; called by muse, mutect2
- ONECUT2 | c.1312C>T p.R438C | Missense Mutation (SNP) | VAF 9/60 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1449358331, COSV72153018; called by muse, mutect2
- OR10K1 | c.303G>A p.M101I | Missense Mutation (SNP) | VAF 12/213 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.958); catalogued as rs866434621, COSV56873154; called by muse, mutect2
- OR10K2 | c.37A>T p.I13F | Missense Mutation (SNP) | VAF 4/64 reads (6%) | SIFT tolerated (0.06); PolyPhen benign (0.1); catalogued as COSV59222097; called by muse, mutect2
- OR11H12 | c.410A>T p.Q137L | Missense Mutation (SNP) | VAF 18/300 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.001); catalogued as rs1486558459; called by muse, mutect2
- OR4A47 | c.749T>A p.V250D | Missense Mutation (SNP) | VAF 20/210 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.933); catalogued as COSV71445078; called by muse, mutect2
- OR51L1 | c.598T>C p.Y200H | Missense Mutation (SNP) | VAF 12/73 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58625302; called by muse, mutect2
- OR6K6 | c.332C>T p.S111F (on ENST00000368144; = p.S87F on NM_001005184.1) | Missense Mutation (SNP) | VAF 10/245 reads (4%) | SIFT tolerated (0.06); PolyPhen benign (0.382); catalogued as COSV63744219, COSV63744589; called by muse, mutect2
- OR8J1 | c.125A>G p.N42S | Missense Mutation (SNP) | VAF 7/140 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV57317748, COSV57319354; called by muse, mutect2
- P2RY6 | c.451G>A p.V151M | Missense Mutation (SNP) | VAF 7/69 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.647); catalogued as rs374484031; called by muse, mutect2, varscan2
- PAGE4 | c.199G>C p.D67H | Missense Mutation (SNP) | VAF 7/47 reads (15%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.67); catalogued as COSV54334974; called by muse, mutect2
- PCDHB7 | c.1531G>A p.G511S | Missense Mutation (SNP) | VAF 9/150 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as rs782316027, COSV50795943; called by muse, mutect2
- PDCD11 | c.4051G>C p.A1351P | Missense Mutation (SNP) | VAF 14/177 reads (8%) | SIFT tolerated (0.06); PolyPhen benign (0.424); catalogued as COSV63934699; called by muse, mutect2
- PER3 | c.1549G>T p.V517L | Missense Mutation (SNP) | VAF 11/178 reads (6%) | SIFT tolerated (0.42); PolyPhen benign (0.001); catalogued as COSV62707060; called by muse, mutect2
- PEX14 | c.649A>G p.N217D | Missense Mutation (SNP) | VAF 38/110 reads (35%) | SIFT tolerated (0.47); PolyPhen benign (0.01); catalogued as COSV63062520; called by muse, mutect2, varscan2
- PFAS | c.1979G>C p.S660T | Missense Mutation (SNP) | VAF 6/90 reads (7%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100119190, COSV58982137; called by muse, mutect2
- PPP2R2C | c.489C>G p.S163R | Missense Mutation (SNP) | VAF 13/159 reads (8%) | SIFT tolerated (0.55); PolyPhen benign (0.007); catalogued as rs1385100274, COSV58671899, COSV58674664; called by muse, mutect2
- PREX2 | c.329T>C p.L110P | Missense Mutation (SNP) | VAF 5/35 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1563503124, COSV55788652, COSV55795891; called by muse, mutect2, varscan2
- PTPRD | c.694C>T p.R232C | Missense Mutation (SNP) | VAF 17/99 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV61927786; called by muse, mutect2, varscan2
- QPCTL | c.23G>C p.R8P | Missense Mutation (SNP) | VAF 4/21 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.995); catalogued as COSV50004433; called by muse, mutect2, varscan2
- RANBP2 | c.3608G>A p.R1203H | Missense Mutation (SNP) | VAF 11/121 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51705462; called by muse, mutect2
- RBM4 | c.685C>T p.R229W | Missense Mutation (SNP) | VAF 24/68 reads (35%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.895); catalogued as COSV59519735; called by muse, mutect2, varscan2
- RFX7 | c.1655C>G p.P552R (on ENST00000559447 / NM_001368074.1; = p.P649R on NM_022841.7 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 10/51 reads (20%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.015); catalogued as COSV57965502, COSV57966707; called by muse, mutect2, varscan2
- RNF217 | c.1468C>T p.R490* (on ENST00000521654 / NM_001286398.2; = p.R198* on NM_152553.5) | Nonsense Mutation (SNP) | VAF 15/150 reads (10%) | catalogued as rs1421492466, COSV51576680; called by muse, mutect2, varscan2
- SEMA3D | c.284T>A p.L95Q | Missense Mutation (SNP) | VAF 9/175 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.934); catalogued as COSV52399407; called by muse, mutect2
- SH3PXD2B | c.1285A>G p.S429G | Missense Mutation (SNP) | VAF 6/23 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.854); catalogued as COSV61128579; called by muse, mutect2, varscan2
- SLC24A2 | c.803T>A p.L268H | Missense Mutation (SNP) | VAF 10/53 reads (19%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.928); catalogued as COSV53870787; called by muse, mutect2, varscan2
- SLCO6A1 | c.212A>G p.K71R | Missense Mutation (SNP) | VAF 10/97 reads (10%) | SIFT tolerated (0.51); PolyPhen benign (0.003); catalogued as COSV65813124; called by muse, mutect2, varscan2
- SLITRK1 | c.1204A>C p.I402L | Missense Mutation (SNP) | VAF 25/298 reads (8%) | SIFT deleterious (0); PolyPhen benign (0); catalogued as COSV65676860; called by muse, mutect2
- SMARCAL1 | c.167A>G p.N56S | Missense Mutation (SNP) | VAF 6/98 reads (6%) | SIFT tolerated, low confidence (0.36); PolyPhen benign (0.001); catalogued as COSV61922528; called by muse, mutect2
- SMARCC2 | c.1459C>T p.R487C | Missense Mutation (SNP) | VAF 10/172 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV57221991; called by muse, mutect2
- SPOPL | c.1156C>T p.R386C | Missense Mutation (SNP) | VAF 21/405 reads (5%) | SIFT tolerated (0.28); PolyPhen benign (0.024); catalogued as rs142534399, COSV54511514; called by muse, mutect2
- SYNE1 | c.21531A>C p.Q7177H (on ENST00000367255 / NM_182961.4; = p.Q7106H on NM_033071.3) | Missense Mutation (SNP) | VAF 11/94 reads (12%) | SIFT tolerated (0.06); PolyPhen benign (0.086); catalogued as COSV55020376; called by muse, mutect2, varscan2
- TDRD3 | c.839A>T p.K280I | Missense Mutation (SNP) | VAF 6/71 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52160814; called by muse, mutect2
- THSD7A | c.246G>T p.R82S | Missense Mutation (SNP) | VAF 14/230 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101448803; called by muse, mutect2
- TIAM1 | c.4390G>A p.A1464T | Missense Mutation (SNP) | VAF 15/100 reads (15%) | SIFT tolerated (0.57); PolyPhen benign (0); catalogued as rs754307192, COSV54556810; called by muse, mutect2, varscan2
- TMEM132D | c.1261A>T p.S421C | Missense Mutation (SNP) | VAF 18/220 reads (8%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.995); catalogued as COSV70615791; called by muse, mutect2
- TPR | c.2123G>A p.R708Q | Missense Mutation (SNP) | VAF 8/68 reads (12%) | SIFT tolerated (0.06); PolyPhen benign (0.048); catalogued as rs781372334, COSV66603432; called by muse, mutect2, varscan2
- TRPC4 | c.2860G>T p.D954Y (on ENST00000379705 / NM_016179.4; = p.D959Y on NM_003306.3) | Missense Mutation (SNP) | VAF 11/94 reads (12%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.133); catalogued as COSV59009206; called by muse, mutect2, varscan2
- TRPC4 | c.2392G>A p.D798N (on ENST00000379705 / NM_016179.4; = p.D803N on NM_003306.3) | Missense Mutation (SNP) | VAF 8/86 reads (9%) | SIFT tolerated (0.19); PolyPhen benign (0.272); catalogued as COSV59003042, COSV59009226; called by muse, mutect2
- TRPS1 | c.943A>C p.T315P (on ENST00000220888 / NM_001330599.2; = p.T328P on NM_014112.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 16/113 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as COSV55247838, COSV55253732; called by muse, mutect2, varscan2
- ZEB2 | c.2540A>C p.N847T | Missense Mutation (SNP) | VAF 8/98 reads (8%) | SIFT tolerated (0.09); PolyPhen benign (0.037); catalogued as COSV57962028; called by muse, mutect2
- ZNF347 | c.2098C>T p.Q700* | Nonsense Mutation (SNP) | VAF 14/145 reads (10%) | catalogued as COSV61970025; called by muse, mutect2, varscan2
- ZNF550 | c.269A>G p.H90R | Missense Mutation (SNP) | VAF 15/147 reads (10%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as COSV57306802; called by muse, mutect2, varscan2
- ZNF574 | c.2252C>T p.T751M | Missense Mutation (SNP) | VAF 24/192 reads (13%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.848); catalogued as rs1209446433, COSV55905624; called by muse, mutect2, varscan2
- ZNF613 | c.596A>T p.N199I (on ENST00000293471 / NM_001031721.4; = p.N163I on NM_024840.4) | Missense Mutation (SNP) | VAF 43/372 reads (12%) | SIFT deleterious (0.04); PolyPhen benign (0.143); catalogued as COSV53273116; called by muse, mutect2, varscan2
- ZNF804A | c.1139T>G p.V380G | Missense Mutation (SNP) | VAF 8/62 reads (13%) | SIFT tolerated (0.54); PolyPhen benign (0); catalogued as COSV56461419, COSV56474751; called by muse, mutect2, varscan2
- CDK5RAP2 | c.3129_3131dup p.Q1044dup | In Frame Ins (INS) | VAF 55/143 reads (38%) | called by mutect2, pindel, varscan2
- GBP7 | c.591T>A p.D197E | Missense Mutation (SNP) | VAF 6/130 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.658); called by muse, mutect2
- OR8G5 | c.199T>G p.S67A | Missense Mutation (SNP) | VAF 5/94 reads (5%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2
- PCDHAC1 | c.459_461dup p.G154dup | In Frame Ins (INS) | VAF 19/79 reads (24%) | called by mutect2, pindel, varscan2
- USP38 | c.2029del p.T677Pfs*2 | Frame Shift Del (DEL) | VAF 28/139 reads (20%) | called by mutect2, pindel, varscan2
- ACSL1 | c.969C>T p.A323= | Silent (SNP) | VAF 6/94 reads (6%) | catalogued as COSV99860803; called by muse, mutect2
- ADCY1 | c.1569C>A p.P523= | Silent (SNP) | VAF 28/42 reads (67%) | catalogued as COSV52039261; called by muse, mutect2, varscan2
- C2CD3 | c.1104T>C p.S368= | Silent (SNP) | VAF 16/66 reads (24%) | catalogued as COSV58096900; called by muse, mutect2, varscan2
- CFHR3 | c.405T>C p.S135= | Silent (SNP) | VAF 7/117 reads (6%) | catalogued as COSV66402859; called by muse, mutect2
- CTTNBP2 | c.1212C>T p.N404= | Silent (SNP) | VAF 17/185 reads (9%) | catalogued as rs555089817, COSV50434272; called by muse, mutect2
- DSCAM | c.264T>G p.P88= | Silent (SNP) | VAF 12/94 reads (13%) | catalogued as COSV68648924; called by muse, mutect2, varscan2
- EDNRB | c.951G>T p.V317= (on ENST00000377211 / NM_001201397.1; = p.V227= on NM_000115.5) | Silent (SNP) | VAF 16/181 reads (9%) | catalogued as COSV57525876; called by muse, mutect2
- ENOX1 | c.1182C>T p.I394= | Silent (SNP) | VAF 11/54 reads (20%) | catalogued as COSV54909674; called by muse, mutect2, varscan2
- FAM83H | c.192G>A p.V64= | Silent (SNP) | VAF 12/129 reads (9%) | catalogued as COSV66354309; called by muse, mutect2
- FAT4 | c.14178T>A p.P4726= | Silent (SNP) | VAF 9/97 reads (9%) | catalogued as COSV58699188; called by muse, mutect2
- GAREM1 | c.1185C>T p.L395= | Silent (SNP) | VAF 13/89 reads (15%) | catalogued as COSV52513317; called by muse, mutect2, varscan2
- GPR21 | c.75C>T p.V25= | Silent (SNP) | VAF 10/140 reads (7%) | catalogued as COSV65379125; called by muse, mutect2
- H3C8 | c.114A>G p.K38= | Silent (SNP) | VAF 32/80 reads (40%) | catalogued as COSV59953439; called by muse, mutect2, varscan2
- HNRNPM | c.958C>T p.L320= | Silent (SNP) | VAF 6/48 reads (13%) | catalogued as COSV57693783, COSV57694993; called by mutect2, varscan2
- KPRP | c.429T>G p.T143= | Silent (SNP) | VAF 40/224 reads (18%) | catalogued as COSV64220881, COSV64221403; called by muse, mutect2, varscan2
- KRTAP13-3 | c.273T>C p.S91= | Silent (SNP) | VAF 7/62 reads (11%) | catalogued as COSV61879462, COSV61879897, COSV61880010; called by muse, mutect2, varscan2
- KTN1 | c.1992T>A p.A664= | Silent (SNP) | VAF 9/83 reads (11%) | catalogued as rs1379189488, COSV68024118; called by muse, mutect2
- LRRC10 | c.666T>C p.N222= | Silent (SNP) | VAF 6/45 reads (13%) | catalogued as COSV64060585; called by muse, mutect2, varscan2
- LRRC4C | c.1356T>A p.S452= | Silent (SNP) | VAF 11/149 reads (7%) | catalogued as COSV53424090, COSV53432939; called by muse, mutect2
- LRRC66 | c.324A>G p.L108= | Silent (SNP) | VAF 17/90 reads (19%) | catalogued as COSV58635611; called by muse, mutect2, varscan2
- MAGEB6 | c.150T>C p.G50= | Silent (SNP) | VAF 7/45 reads (16%) | catalogued as COSV66872682; called by muse, mutect2, varscan2
- MYH7B | c.3858G>C p.L1286= | Silent (SNP) | VAF 8/86 reads (9%) | catalogued as rs1425839801, COSV52682589; called by muse, mutect2
- NPAS3 | c.1518G>A p.A506= (on ENST00000356141 / NM_001164749.2; = p.A474= on NM_022123.3) | Silent (SNP) | VAF 4/40 reads (10%) | catalogued as COSV60849667; called by muse, mutect2
- NPC1 | c.2067C>T p.V689= | Silent (SNP) | VAF 6/72 reads (8%) | catalogued as COSV52581529; called by muse, mutect2
- OR2T10 | c.738A>T p.T246= | Silent (SNP) | VAF 9/62 reads (15%) | catalogued as COSV57897625; called by muse, mutect2, varscan2
- OR2T6 | c.165C>A p.L55= | Silent (SNP) | VAF 39/73 reads (53%) | catalogued as COSV63216816; called by muse, mutect2, varscan2
- OR2W1 | c.327A>G p.S109= | Silent (SNP) | VAF 5/75 reads (7%) | catalogued as COSV65851778; called by muse, mutect2
- PCDH11X | c.555T>C p.F185= | Silent (SNP) | VAF 6/36 reads (17%) | catalogued as COSV100013318; called by mutect2, varscan2
- POFUT1 | c.396G>A p.Q132= | Silent (SNP) | VAF 8/236 reads (3%) | catalogued as COSV65260351; called by muse, mutect2
- PREX2 | c.4287T>C p.F1429= | Silent (SNP) | VAF 11/95 reads (12%) | catalogued as COSV55788686; called by muse, mutect2
- PSKH1 | c.582C>T p.D194= | Silent (SNP) | VAF 4/30 reads (13%) | catalogued as rs751642054, COSV52124324; called by mutect2, varscan2
- PTPRB | c.1770C>T p.I590= | Silent (SNP) | VAF 7/186 reads (4%) | catalogued as COSV54248135; called by muse, mutect2
- PTPRC | c.2691A>G p.Q897= | Silent (SNP) | VAF 16/136 reads (12%) | catalogued as COSV61405854, COSV61412086, COSV61419400; called by muse, mutect2, varscan2
- RAB34 | c.165C>A p.V55= | Silent (SNP) | VAF 10/144 reads (7%) | catalogued as COSV56386351; called by muse, mutect2
- RAP1GAP | c.1476G>A p.P492= | Silent (SNP) | VAF 22/94 reads (23%) | catalogued as rs747101742, COSV51575781; called by muse, mutect2, varscan2
- RTN2 | c.762G>A p.Q254= | Silent (SNP) | VAF 10/112 reads (9%) | catalogued as COSV55595247; called by muse, mutect2
- RYR2 | c.1467C>T p.F489= | Silent (SNP) | VAF 5/17 reads (29%) | catalogued as rs781662848, COSV63671973, COSV63701540; called by muse, mutect2, varscan2
- SZT2 | c.8031G>A p.A2677= (on ENST00000634258 / NM_001365999.1; = p.A2620= on NM_015284.4) | Silent (SNP) | VAF 7/55 reads (13%) | catalogued as rs138303356; ClinVar: likely benign; called by muse, mutect2, varscan2
- TBL2 | c.1185G>A p.A395= | Silent (SNP) | VAF 5/48 reads (10%) | catalogued as rs920522610, COSV59787808; called by muse, mutect2, varscan2
- TCERG1L | c.477T>A p.I159= | Silent (SNP) | VAF 5/38 reads (13%) | catalogued as COSV100894397; called by muse, mutect2, varscan2
- TLN2 | c.6081G>A p.L2027= | Silent (SNP) | VAF 18/81 reads (22%) | catalogued as rs769329836, COSV60892864; called by muse, mutect2, varscan2
- TPD52 | c.537A>G p.E179= (on ENST00000379097 / NM_001025252.3; = p.E139= on NM_005079.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 6/71 reads (8%) | catalogued as COSV66951278; called by muse, mutect2
- TRA2A | c.555G>A p.L185= | Silent (SNP) | VAF 23/276 reads (8%) | catalogued as COSV51717961; called by muse, mutect2
- TTC12 | c.1890T>G p.G630= | Silent (SNP) | VAF 8/112 reads (7%) | catalogued as COSV59099089; called by muse, mutect2
- WIPF1 | c.435T>C p.S145= | Silent (SNP) | VAF 7/38 reads (18%) | catalogued as COSV55818240; called by muse, mutect2, varscan2
- ZDHHC11 | c.825C>T p.N275= | Silent (SNP) | VAF 16/322 reads (5%) | catalogued as COSV52073380; called by muse, mutect2
- ZNF248 | c.1176G>A p.K392= | Silent (SNP) | VAF 10/102 reads (10%) | catalogued as COSV61998170; called by muse, mutect2, varscan2
- FYN | c.862+464C>T | Intron (SNP) | VAF 6/58 reads (10%) | catalogued as COSV99992147; called by muse, mutect2, varscan2
- KLHL4 | c.*2819T>G | 3'UTR (SNP) | VAF 11/43 reads (26%) | catalogued as COSV100910013; called by muse, mutect2, varscan2
- TPM4 | c.*283A>G | 3'UTR (SNP) | VAF 12/101 reads (12%) | catalogued as COSV56289558; called by muse, mutect2, varscan2
